Somatic mutation profile of tumor specimen TCGA-4Z-AA81-01A (aliquot TCGA-4Z-AA81-01A-11D-A391-08) from TCGA case TCGA-4Z-AA81, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 80.6 years (29,457 days).
Specimen TCGA-4Z-AA81-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d69088be-0732-48b6-9b81-6c67ae665c35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4Z-AA81-10A (Blood Derived Normal), aliquot TCGA-4Z-AA81-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10590dd2-f195-4618-8652-2e7dfd536271

The open-access MAF lists 237 somatic variants for this specimen: 179 protein-altering or splice-affecting, 55 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 150, Silent 55, Nonsense Mutation 19, Frame Shift Del 5, Splice Site 3, 3'UTR 1, In Frame Del 1, Intron 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 16/89 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as COSV57246601, COSV57252959; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 190/249 reads (76%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.4393G>C p.D1465H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1413474, COSV57058766; called by muse, mutect2, varscan2
- ABCA4 | c.581G>C p.G194A | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.554); catalogued as rs780256905, COSV64670875, COSV64676929; called by muse, mutect2, varscan2
- ABCC10 | c.2098G>C p.E700Q (on ENST00000372530 / NM_001198934.2; = p.E672Q on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV55090576, COSV55092987; called by muse, mutect2
- ABI2 | c.764G>A p.R255Q (on ENST00000295851 / NM_001375719.1; = p.R249Q on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.594); catalogued as rs771624986, COSV53695429; called by muse, mutect2, varscan2
- ABL1 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); catalogued as rs1423422276, COSV59338766; called by muse, mutect2, varscan2
- ADAR | c.1282G>C p.E428Q | Missense Mutation (SNP) | VAF 60/205 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.081); catalogued as COSV52719913; called by muse, mutect2, varscan2
- ADCY5 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as rs1275425809, COSV101518463; called by muse, varscan2
- AIMP2 | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs200362634, COSV99764581; called by mutect2, varscan2
- AKT1S1 | c.433G>A p.E145K (on ENST00000344175 / NM_001098633.4; = p.E165K on NM_032375.5) | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV59277416; called by muse, mutect2, varscan2
- ALYREF | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | catalogued as COSV100485788, COSV100485841; called by muse, mutect2, varscan2
- AP3B2 | c.2549C>G p.S850C (on ENST00000261722; = p.S844C on NM_004644.5) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV55613287; called by muse, mutect2, varscan2
- ARHGAP11A | c.805G>T p.E269* | Nonsense Mutation (SNP) | VAF 29/132 reads (22%) | catalogued as COSV100853362; called by muse, mutect2, varscan2
- ARHGAP36 | c.1468A>G p.S490G | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV52271008; called by muse, mutect2, varscan2
- ARID4A | c.2901G>C p.L967F | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.158); catalogued as COSV62166132; called by muse, mutect2, varscan2
- BAZ2B | c.5813G>A p.R1938Q | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.398); catalogued as rs764943316, COSV58596141; called by muse, mutect2, varscan2
- BAZ2B | c.2752G>C p.E918Q | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV54276546; called by muse, mutect2, varscan2
- BICRAL | c.1606G>A p.G536R | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as COSV58404909, COSV58408018; called by muse, mutect2, varscan2
- BNIPL | c.847C>G p.R283G | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV54848559; called by muse, mutect2, varscan2
- BRCA2 | c.8827C>G p.Q2943E | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66460875; called by muse, mutect2, varscan2
- BRD8 | c.2852C>G p.S951C | Missense Mutation (SNP) | VAF 63/103 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.808); catalogued as rs1561601656, COSV50164886; called by muse, mutect2, varscan2
- BUB3 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | catalogued as COSV100922283; called by muse, mutect2, varscan2
- BZW1 | c.56G>A p.R19K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV68419394; called by muse, mutect2, varscan2
- C10orf71 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.151); catalogued as COSV60511734; called by muse, mutect2, varscan2
- C3orf70 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV58590153; called by muse, mutect2, varscan2
- CAMK2B | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.14); catalogued as COSV51665544; called by muse, mutect2, varscan2
- CCDC172 | c.387G>T p.M129I | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100319630, COSV60939872; called by muse, mutect2, varscan2
- CD2BP2 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 37/248 reads (15%) | catalogued as COSV99977248; called by muse, mutect2, varscan2
- CERS3 | c.880C>T p.H294Y | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1011622454, COSV52573465; called by muse, mutect2, varscan2
- CFAP58 | c.1958G>C p.R653T | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV63832678, COSV63834200, COSV63835828; called by muse, mutect2, varscan2
- CFAP65 | c.646-1G>A p.X216_splice | Splice Site (SNP) | VAF 30/55 reads (55%) | catalogued as COSV55391636; called by muse, mutect2, varscan2
- CHD7 | c.1597C>A p.H533N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.062); catalogued as COSV71113774; called by muse, mutect2, varscan2
- CIART | c.105G>C p.E35D | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.994); catalogued as COSV51745848; called by muse, mutect2, varscan2
- CLDN22 | c.529C>G p.L177V | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60109816; called by muse, mutect2, varscan2
- CLK2 | c.979G>C p.D327H (on ENST00000368361 / NM_001294339.2; = p.D326H on NM_003993.4) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56943715, COSV56944030; called by muse, mutect2, varscan2
- CNOT3 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55360792; called by muse, mutect2
- CNPPD1 | c.520C>G p.L174V | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.509); catalogued as rs760814819, COSV55409191; called by muse, mutect2, varscan2
- CNTLN | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV52093505; called by muse, mutect2, varscan2
- COG5 | c.1777G>C p.E593Q (on ENST00000347053 / NM_001379512.1; = p.E614Q on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV51761824; called by muse, mutect2, varscan2
- COL2A1 | c.3874G>A p.E1292K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100476476, COSV61531316, COSV61533436; called by muse, mutect2, varscan2
- CR2 | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.37); catalogued as rs1462613547, COSV65509338; called by muse, mutect2, varscan2
- CREBBP | c.4560+1G>A p.X1520_splice | Splice Site (SNP) | VAF 23/93 reads (25%) | catalogued as CS084692, COSV52137467; called by muse, mutect2, varscan2
- CUBN | c.5899G>A p.D1967N | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV64724871; called by muse, mutect2, varscan2
- CUL9 | c.1846G>T p.A616S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as COSV52733205; called by muse, mutect2, varscan2
- CXCL9 | c.209G>C p.G70A | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.809); catalogued as rs890060522, COSV53579563; called by muse, mutect2, varscan2
- DCAF4 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV62320377; called by muse, mutect2, varscan2
- DDX18 | c.342G>C p.K114N | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.074); catalogued as COSV54307349; called by muse, mutect2, varscan2
- DIPK2A | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as rs756937184, COSV59857695; called by muse, mutect2, varscan2
- EEFSEC | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.048); catalogued as COSV54631555; called by mutect2, varscan2
- EIF3B | c.1311C>G p.F437L | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as COSV62803057, COSV62804571; called by muse, mutect2, varscan2
- EIF4A2 | c.1203G>A p.M401I | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV56216304, COSV56217667; called by muse, mutect2, varscan2
- ENO3 | c.829G>T p.G277* | Nonsense Mutation (SNP) | VAF 33/258 reads (13%) | catalogued as COSV52777990, COSV99236833; called by muse, mutect2, varscan2
- EP300 | c.3244C>T p.Q1082* | Nonsense Mutation (SNP) | VAF 42/176 reads (24%) | catalogued as COSV54332154; called by muse, mutect2, varscan2
- EPHA8 | c.2191C>A p.Q731K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs1442302244, COSV51272730, COSV51290819; called by muse, mutect2, varscan2
- EVPL | c.3478G>A p.E1160K | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs763830732, COSV56909883; called by muse, mutect2
- EXOC3L2 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as COSV52972841; called by muse, mutect2, varscan2
- FKBP6 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV52722518; called by muse, mutect2, varscan2
- FMN2 | c.4259G>T p.R1420L | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV60449095, COSV60452229; called by muse, mutect2, varscan2
- GCN1 | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs749959129, COSV56112665; called by muse, mutect2, varscan2
- GIGYF2 | c.1071G>C p.E357D | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV65252820; called by muse, mutect2, varscan2
- GLRA1 | c.319C>G p.P107A | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as COSV51012458, COSV51023299; called by muse, mutect2, varscan2
- GNAI2 | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as rs150943193; called by muse, mutect2, varscan2
- GPR107 | c.1306G>A p.G436S (on ENST00000372406 / NM_001136557.2; = p.A436T on NM_020960.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.686); catalogued as rs1432526860, COSV61282128; called by muse, mutect2, varscan2
- GTF3C4 | c.1036A>G p.N346D | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.366); catalogued as COSV64645948; called by muse, mutect2, varscan2
- HECTD4 | c.13118C>T p.S4373F | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV66398166; called by muse, mutect2, varscan2
- HELZ | c.5291C>A p.S1764Y | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); catalogued as COSV100699074; called by mutect2, varscan2
- HIPK3 | c.1591C>G p.L531V | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.068); catalogued as COSV57565063; called by muse, mutect2, varscan2
- HNF4G | c.658C>G p.L220V (on ENST00000354370 / NM_001330561.2; = p.L267V on NM_004133.5) | Missense Mutation (SNP) | VAF 50/265 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.612); catalogued as COSV62972706; called by muse, mutect2, varscan2
- HOXA6 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762684090, COSV56072569; called by muse, mutect2, varscan2
- IFNA14 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 60/317 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs370576305, COSV66516390; called by muse, mutect2, varscan2
- IL17RD | c.1566del p.Q523Sfs*66 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | catalogued as rs1185022730; called by mutect2, pindel, varscan2
- IL21R | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs374130131; called by muse, mutect2, varscan2
- IQSEC1 | c.2281G>A p.E761K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV56228035; called by muse, mutect2, varscan2
- ITFG2 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs922239753, COSV57390828; called by muse, mutect2, varscan2
- KCNA5 | c.1633G>A p.G545R | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.08); catalogued as COSV52908117; called by muse, mutect2, varscan2
- KCNT1 | c.1025G>A p.G342D (on ENST00000488444; = p.G361D on NM_020822.3) | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV99706726; called by muse, mutect2
- KCNU1 | c.464T>G p.L155W | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1328088457, COSV101299436; called by muse, mutect2
- KHDRBS2 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs142287079, COSV55484670; called by muse, mutect2, varscan2
- KIF17 | c.2864C>G p.S955C | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV56121657; called by muse, mutect2, varscan2
- KIF1A | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as rs375290825, COSV57508382; called by muse, varscan2
- KIF7 | c.3515G>A p.R1172Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as rs1275424943, COSV51545872; called by muse, mutect2, varscan2
- KIFAP3 | c.2163C>G p.F721L | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as COSV63036533; called by muse, mutect2, varscan2
- KIFAP3 | c.1452G>A p.M484I | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV63036544; called by muse, mutect2, varscan2
- KLHL42 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.044); catalogued as COSV67146152; called by muse, mutect2, varscan2
- KMT2D | c.13645G>A p.E4549K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs1238014538, COSV56477609; called by muse, mutect2, varscan2
- KRT28 | c.1392C>G p.F464L | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV60686324; called by muse, mutect2, varscan2
- LAMA3 | c.6172G>C p.E2058Q (on ENST00000313654 / NM_198129.4; = p.E449Q on NM_000227.6) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.791); catalogued as COSV52541568; called by muse, mutect2, varscan2
- LGI4 | c.1538G>A p.R513K | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV59534724; called by muse, mutect2, varscan2
- LONRF3 | c.1413G>C p.M471I (on ENST00000371628 / NM_001031855.3; = p.M430I on NM_024778.5) | Missense Mutation (SNP) | VAF 39/47 reads (83%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as COSV59156018; called by muse, mutect2, varscan2
- LRP1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV54522941; called by muse, mutect2, varscan2
- MBNL2 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100600388, COSV59124815; called by muse, mutect2, varscan2
- MBTPS1 | c.2716C>A p.H906N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV58572253; called by muse, mutect2, varscan2
- MEIS3 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV100520559; called by muse, mutect2
- MEOX2 | c.654C>G p.Y218* | Nonsense Mutation (SNP) | VAF 33/106 reads (31%) | catalogued as COSV100012543; called by muse, mutect2, varscan2
- MLLT10 | c.1091C>G p.S364C | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.936); catalogued as COSV57002843; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as COSV56623752; called by muse, mutect2, varscan2
- MRM3 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100022800, COSV100022827; called by muse, mutect2, varscan2
- MYLK4 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs371252859; called by muse, mutect2, varscan2
- MYO18B | c.3286T>G p.Y1096D | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59145670; called by muse, mutect2
- NAT2 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.3); catalogued as COSV54063021; called by mutect2, varscan2
- NCOR1 | c.6728C>T p.T2243M | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as rs571174228, COSV51991485; called by muse, mutect2, varscan2
- NDC80 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.318); catalogued as COSV55249449; called by muse, mutect2, varscan2
- NDUFA9 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as rs1458201753, COSV56927857; called by muse, mutect2
- NIPAL3 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs761574692, COSV50236256; called by muse, mutect2, varscan2
- NOXRED1 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV100033240; called by muse, mutect2, varscan2
- NPB | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1253473346, COSV58712436; called by muse, mutect2, varscan2
- OR2D3 | c.632C>T p.T211I | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.152); catalogued as COSV53494586; called by muse, mutect2, varscan2
- OR4A47 | c.442del p.V148Lfs*36 | Frame Shift Del (DEL) | VAF 17/74 reads (23%) | catalogued as COSV101487052; called by mutect2, pindel, varscan2
- OR8B4 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.179); catalogued as rs868185010, COSV62070399; called by muse, mutect2, varscan2
- PCYOX1L | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV51004612; called by muse, mutect2, varscan2
- PDGFRA | c.2348C>T p.S783L | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.062); catalogued as COSV57272456; called by muse, mutect2, varscan2
- PHF20 | c.2317G>C p.D773H | Missense Mutation (SNP) | VAF 70/125 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64977394; called by muse, mutect2, varscan2
- PIWIL2 | c.774C>G p.F258L | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs73225895, COSV63253625; called by muse, mutect2, varscan2
- PLD5 | c.1121G>A p.R374Q (on ENST00000442594; = p.R312Q on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV59163972; called by muse, mutect2, varscan2
- PLVAP | c.449T>C p.M150T | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV53087252; called by muse, mutect2, varscan2
- PODXL2 | c.998C>A p.S333Y | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV61066356; called by muse, mutect2, varscan2
- POLR2M | c.187G>T p.A63S | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.16); catalogued as COSV55211648; called by muse, mutect2, varscan2
- POP1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV62893973; called by muse, mutect2, varscan2
- PRAMEF4 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 18/205 reads (9%) | catalogued as rs1388509831, COSV99340259; called by muse, mutect2, varscan2
- PRKDC | c.6400G>A p.G2134R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.548); catalogued as rs1195009342, COSV58061166; called by muse, mutect2, varscan2
- PRKDC | c.2345G>A p.R782K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58068151; called by muse, mutect2, varscan2
- PRPF6 | c.2713G>A p.E905K | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99412856; called by muse, mutect2
- PYDC1 | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV57250646, COSV57252095; called by muse, mutect2, varscan2
- RB1 | c.2590G>T p.E864* | Nonsense Mutation (SNP) | VAF 21/76 reads (28%) | catalogued as COSV57299646; called by muse, mutect2, varscan2
- RB1CC1 | c.4537G>A p.E1513K | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as rs1194300457, COSV50263182, COSV50269449; called by muse, mutect2, varscan2
- RBM12B | c.1507G>C p.E503Q | Missense Mutation (SNP) | VAF 77/170 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs371589399, COSV67897331; called by muse, mutect2, varscan2
- RDH16 | c.433A>T p.T145S | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV62457963; called by muse, mutect2, varscan2
- RFFL | c.721C>G p.L241V | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1460524926, COSV52073823; called by muse, mutect2, varscan2
- RHO | c.105G>A p.W35* | Nonsense Mutation (SNP) | VAF 38/92 reads (41%) | catalogued as rs771123958, COSV99960795; called by muse, mutect2, varscan2
- RNF216 | c.751G>A p.D251N (on ENST00000425013 / NM_207116.3; = p.D308N on NM_207111.4) | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV66290621; called by muse, mutect2, varscan2
- RPS6KA6 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV99425481; called by muse, mutect2, varscan2
- RSPO2 | c.334A>C p.K112Q | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52653909; called by muse, mutect2, varscan2
- RYR2 | c.9809C>T p.S3270L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV100772945; called by muse, mutect2
- SCMH1 | c.614G>A p.R205Q (on ENST00000326197 / NM_001031694.2; = p.R158Q on NM_012236.4) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as rs914942940, COSV58239057; called by muse, mutect2, varscan2
- SHOC1 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as COSV59506362; called by muse, mutect2, varscan2
- SIN3A | c.2413C>G p.Q805E | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV64584545; called by muse, varscan2
- SIPA1L2 | c.4885G>A p.E1629K | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.995); catalogued as rs373866889, COSV99479030; called by muse, mutect2, varscan2
- SLC43A2 | c.878_879insAC p.L294Rfs*11 | Frame Shift Ins (INS) | VAF 16/73 reads (22%) | catalogued as COSV56770870; called by mutect2, pindel, varscan2
- SLC7A10 | c.1320C>A p.F440L | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.812); catalogued as COSV53506755, COSV99471994; called by muse, mutect2, varscan2
- SORCS1 | c.2794G>T p.E932* | Nonsense Mutation (SNP) | VAF 17/105 reads (16%) | catalogued as rs1230150101, COSV53870704, COSV99550529; called by muse, mutect2, varscan2
- SP140 | c.1809G>C p.K603N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV59448489, COSV59454103; called by muse, mutect2, varscan2
- SPAG17 | c.4719G>A p.M1573I | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs749203278, COSV60466350; called by muse, mutect2, varscan2
- SPART | c.584C>A p.S195* | Nonsense Mutation (SNP) | VAF 21/61 reads (34%) | catalogued as COSV100768869, COSV62088752; called by muse, mutect2, varscan2
- SPATA31A1 | c.3236G>A p.R1079K | Missense Mutation (SNP) | VAF 95/213 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.229); catalogued as COSV66533870; called by muse, mutect2, varscan2
- SPEF2 | c.705G>T p.M235I | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV56794738, COSV56799909; called by muse, mutect2, varscan2
- SPEG | c.5023G>A p.E1675K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs758577613, COSV100403127, COSV56674740; called by muse, mutect2, varscan2
- ST8SIA1 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV53959134; called by muse, mutect2
- STOM | c.794C>G p.S265* | Nonsense Mutation (SNP) | VAF 27/137 reads (20%) | catalogued as COSV99713864; called by muse, mutect2, varscan2
- SULT2B1 | c.343G>T p.D115Y (on ENST00000201586 / NM_177973.2; = p.D100Y on NM_004605.2) | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV52378296; called by muse, mutect2, varscan2
- SVEP1 | c.6902C>T p.S2301F | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV52839379, COSV52842957; called by muse, mutect2, varscan2
- SYK | c.590G>A p.R197K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV101002631; called by muse, mutect2, varscan2
- SYNE2 | c.6991G>A p.D2331N | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV59966006; called by muse, mutect2, varscan2
- TAOK3 | c.1701G>A p.M567I | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV66827397; called by muse, mutect2, varscan2
- THEM4 | c.671C>G p.S224* | Nonsense Mutation (SNP) | VAF 13/130 reads (10%) | catalogued as COSV100916972; called by muse, mutect2, varscan2
- TMEM106C | c.383A>T p.Q128L | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV56743431; called by muse, mutect2, varscan2
- TMEM139 | c.473G>T p.R158I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV60083258; called by muse, mutect2, varscan2
- TRAK2 | c.798G>A p.M266I | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as COSV60274366; called by muse, mutect2, varscan2
- TRAV27 | c.260G>C p.R87T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs970367657; called by muse, mutect2, varscan2
- TREML4 | c.128C>G p.S43* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | catalogued as COSV100422788, COSV100422996; called by muse, mutect2, varscan2
- TRIM24 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.305); catalogued as COSV58977104; called by muse, varscan2
- TRIP4 | c.789C>G p.I263M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.157); catalogued as COSV56032789; called by muse, mutect2, varscan2
- TRPC5 | c.2896del p.E966Kfs*47 | Frame Shift Del (DEL) | VAF 39/73 reads (53%) | catalogued as COSV53301546; called by mutect2, pindel, varscan2
- TTN | c.84101A>G p.K28034R (on ENST00000591111; = p.K20610R on NM_003319.4) | Missense Mutation (SNP) | VAF 57/153 reads (37%) | PolyPhen probably damaging (0.994); catalogued as COSV60114900; called by muse, mutect2, varscan2
- TUT7 | c.3244G>A p.E1082K | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV52898273; called by muse, mutect2, varscan2
- UBR2 | c.4610-1G>C p.X1537_splice | Splice Site (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100867540; called by muse, mutect2
- UCHL1 | c.198G>C p.Q66H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52652984; called by muse, mutect2, varscan2
- USPL1 | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.148); catalogued as COSV55001884; called by muse, mutect2, varscan2
- UTP20 | c.3977G>C p.R1326T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV55376697; called by muse, mutect2, varscan2
- ZC3H6 | c.2647G>C p.D883H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59670108; called by muse, mutect2, varscan2
- ZFYVE19 | c.1276G>A p.E426K (on ENST00000355341 / NM_001077268.2; = p.E416K on NM_032850.5) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as rs1321851798, COSV54539432, COSV54541983; called by muse, mutect2, varscan2
- ZNF114 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1568995614, COSV59945090; called by muse, mutect2
- ZNF3 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs367859714; called by muse, mutect2, varscan2
- ZNF480 | c.1328C>T p.S443L | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV57997945; called by muse, mutect2, varscan2
- CFAP74 | c.1377G>A p.W459* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- MROH1 | c.4625G>T p.R1542L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- RAD21 | c.1594del p.E532Kfs*80 | Frame Shift Del (DEL) | VAF 28/101 reads (28%) | called by mutect2, pindel, varscan2
- RB1 | c.235del p.E79Rfs*32 | Frame Shift Del (DEL) | VAF 16/85 reads (19%) | called by mutect2, pindel, varscan2
- ZNF84 | c.188_190del p.G63del | In Frame Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- ACTRT3 | c.846T>C p.C282= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV57755145; called by muse, mutect2, varscan2
- AIPL1 | c.531G>A p.A177= | Silent (SNP) | VAF 28/159 reads (18%) | catalogued as rs902464819, COSV51508484; called by muse, mutect2, varscan2
- BTG1 | c.48C>T p.A16= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs779919245, COSV55460212; called by muse, mutect2, varscan2
- CACNA1C | c.813C>A p.I271= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV59709894, COSV59760797; called by muse, mutect2, varscan2
- CARD9 | c.639C>G p.L213= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV53735383; called by muse, mutect2, varscan2
- CCDC146 | c.1503G>A p.K501= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV53553152; called by muse, mutect2, varscan2
- CD96 | c.201G>A p.L67= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV51921312; called by muse, mutect2, varscan2
- COG4 | c.567G>C p.L189= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV60424748; called by muse, mutect2, varscan2
- COPG1 | c.1188C>G p.V396= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV100135492, COSV59116157; called by muse, mutect2, varscan2
- CSPG4 | c.4338G>A p.L1446= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV57900215; called by muse, mutect2, varscan2
- DBH | c.18C>G p.R6= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV55042121; called by muse, mutect2
- DCP1A | c.435G>A p.Q145= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV53690310; called by muse, mutect2, varscan2
- DENND1A | c.2100C>T p.P700= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV65355095; called by muse, mutect2, varscan2
- DENND4B | c.1467C>T p.V489= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs746428006, COSV63411391; called by muse, varscan2
- DNER | c.1659G>A p.L553= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as COSV59174333; called by muse, varscan2
- DOCK8 | c.1635G>A p.L545= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs1422065168, COSV66635577; called by muse, mutect2, varscan2
- FBXO7 | c.510C>T p.L170= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as COSV56680842; called by muse, mutect2, varscan2
- GCH1 | c.702C>T p.F234= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV54303382; called by muse, mutect2, varscan2
- GPHN | c.210G>A p.L70= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV59490773; called by muse, mutect2, varscan2
- GRIK2 | c.915G>A p.P305= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as rs145542805, COSV100028502; called by muse, varscan2
- HNRNPUL1 | c.2529G>A p.G843= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV54191478; called by muse, mutect2, varscan2
- IMPACT | c.177G>C p.P59= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV52421123, COSV52423094; called by muse, mutect2, varscan2
- LMTK3 | c.3573C>T p.L1191= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV54309508; called by muse, mutect2
- LONP2 | c.513G>A p.L171= | Silent (SNP) | VAF 52/108 reads (48%) | catalogued as COSV53525499; called by muse, mutect2, varscan2
- MANBA | c.534C>T p.V178= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV56969524; called by muse, mutect2, varscan2
- MEP1A | c.267G>A p.L89= | Silent (SNP) | VAF 14/117 reads (12%) | catalogued as COSV57922159; called by muse, mutect2, varscan2
- NES | c.2430C>G p.L810= | Silent (SNP) | VAF 59/116 reads (51%) | catalogued as COSV63962579; called by muse, mutect2, varscan2
- NOX5 | c.1734C>A p.I578= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV52994791; called by muse, mutect2, varscan2
- NUMA1 | c.2208C>T p.I736= | Silent (SNP) | VAF 47/97 reads (48%) | catalogued as COSV61189970; called by muse, mutect2, varscan2
- OR8K5 | c.42G>A p.L14= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV57888578, COSV57890644; called by muse, mutect2, varscan2
- ORC4 | c.660A>T p.S220= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as COSV51576486; called by muse, mutect2, varscan2
- PAN2 | c.3489C>T p.F1163= (on ENST00000425394 / NM_001127460.3; = p.F1159= on NM_014871.5) | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as COSV56265030; called by muse, mutect2, varscan2
- PAPSS1 | c.363A>G p.A121= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV54492548; called by muse, mutect2, varscan2
- PDE5A | c.2070G>C p.L690= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV53351927; called by muse, mutect2, varscan2
- PDE6B | c.1581G>T p.L527= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV55329929; called by muse, mutect2, varscan2
- PIGT | c.615G>A p.L205= | Silent (SNP) | VAF 94/154 reads (61%) | catalogued as rs1568947761, COSV54128088; called by muse, mutect2, varscan2
- PLIN5 | c.306G>A p.E102= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV67850980; called by muse, mutect2, varscan2
- PRAMEF10 | c.1098C>T p.L366= | Silent (SNP) | VAF 16/136 reads (12%) | called by muse, mutect2, varscan2
- PTH2R | c.150C>G p.L50= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99782923; called by muse, mutect2
- REP15 | c.165G>C p.L55= | Silent (SNP) | VAF 21/180 reads (12%) | catalogued as COSV57297538; called by muse, mutect2, varscan2
- RPA4 | c.165C>T p.L55= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV61288483; called by muse, mutect2, varscan2
- RRBP1 | c.3933C>G p.L1311= (on ENST00000377813 / NM_001365613.2; = p.L878= on NM_004587.3) | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as COSV99854567; called by muse, mutect2
- SIN3A | c.2331C>G p.L777= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV64584549; called by muse, varscan2
- SLC2A4 | c.873G>A p.A291= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs377321536, COSV99142739; called by muse, mutect2, varscan2
- SNED1 | c.384C>T p.R128= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV60031944; called by muse, mutect2, varscan2
- SORCS1 | c.2793G>A p.T931= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as rs773454923, COSV53898120; called by muse, mutect2, varscan2
- SPTA1 | c.6459C>G p.V2153= | Silent (SNP) | VAF 49/111 reads (44%) | catalogued as COSV100933978, COSV63757978; called by muse, mutect2, varscan2
- STK38 | c.678G>A p.V226= | Silent (SNP) | VAF 35/175 reads (20%) | catalogued as COSV57708892, COSV57709996; called by muse, mutect2, varscan2
- STX1A | c.528C>T p.I176= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV56109862; called by muse, mutect2, varscan2
- TM4SF18 | c.189A>G p.V63= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs1289086647, COSV56059827; called by muse, mutect2, varscan2
- TM7SF2 | c.714C>T p.L238= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV54209156; called by muse, mutect2, varscan2
- TMEM87A | c.1464G>T p.L488= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV67747911; called by muse, mutect2, varscan2
- VDAC2 | c.274C>T p.L92= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs766077938, COSV100041055, COSV53687397; called by muse, mutect2, varscan2
- ZNF135 | c.837C>T p.F279= (on ENST00000313434 / NM_001289401.2; = p.F291= on NM_003436.4) | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV57885129; called by muse, mutect2, varscan2
- ZNF671 | c.84C>T p.L28= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs751755257, COSV58054126; called by mutect2, varscan2
- FGFR3 | c.*1076C>T | 3'UTR (SNP) | VAF 9/39 reads (23%) | catalogued as COSV99603507; called by muse, mutect2, varscan2
- GCH1 | c.*16+137C>G | Intron (SNP) | VAF 9/26 reads (35%) | catalogued as COSV99582107; called by muse, mutect2, varscan2
- TMED3 | c.-1C>T | 5'UTR (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100230097; called by muse, mutect2
